Somatic mutation profile of tumor specimen ALCH-B0FQ-TTP1-A (aliquot ALCH-B0FQ-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0FQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.7 years (20,356 days).
Specimen ALCH-B0FQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c09189c-83a3-4031-b1c0-29200a70eeaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0FQ-NB1-A (Blood Derived Normal), aliquot ALCH-B0FQ-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95726627-5ef4-4a67-8fbb-97386dea9073

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Splice Region 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374795983; called by muse, mutect2
- ADGRL3 | c.554T>A p.L185H (on ENST00000506720 / NM_001322402.2; = p.L117H on NM_015236.6) | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV72267988; called by muse, varscan2
- CHRNA7 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 24/704 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769876615, COSV60970086; called by muse, mutect2
- CROCC2 | c.3166G>A p.V1056I | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs984809518, COSV69132447, COSV69132512; called by muse, mutect2, varscan2
- KCNV1 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.108); catalogued as COSV52088333; called by muse, mutect2
- MYO3A | c.4567C>T p.R1523* | Nonsense Mutation (SNP) | VAF 15/204 reads (7%) | catalogued as rs727504688; called by muse, mutect2
- RGS6 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs750195312, COSV59567926, COSV59595141; called by muse, mutect2
- TENM1 | c.1613G>C p.G538A | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV64447099; called by muse, mutect2, varscan2
- GALNT18 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- MYRFL | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.098); called by muse, mutect2
- PTPRF | c.1418C>A p.T473K | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2
- PTPRR | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 28/826 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- SLC19A2 | c.1029G>T p.L343= | Splice Region (SNP) | VAF 15/409 reads (4%) | called by muse, mutect2
- TMEM175 | c.776A>T p.E259V | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- AP2A1 | c.990C>T p.A330= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV62818678; called by muse, mutect2, varscan2
- BNC1 | c.2904G>A p.S968= | Silent (SNP) | VAF 14/409 reads (3%) | catalogued as rs1021377126, COSV61757413; called by muse, mutect2
- PCDHGA7 | c.480A>C p.P160= | Silent (SNP) | VAF 38/434 reads (9%) | called by muse, mutect2
- PKP3 | c.456G>A p.Q152= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- PLAGL2 | chr20:32189618 G>C | 3'Flank (SNP) | VAF 49/490 reads (10%) | called by muse, mutect2, varscan2
